Somatic mutation profile of tumor specimen TCGA-CK-6747-01A (aliquot TCGA-CK-6747-01A-11D-1835-10) from TCGA case TCGA-CK-6747, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IIA; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CK-6747-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eecdc94b-0032-4c8b-8a4e-27a77ae332d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CK-6747-10A (Blood Derived Normal), aliquot TCGA-CK-6747-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f506dabd-7a3b-49ba-9960-7f1103388195

The open-access MAF lists 184 somatic variants for this specimen: 144 protein-altering or splice-affecting, 33 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 33, Frame Shift Del 30, In Frame Del 23, Nonsense Mutation 8, Splice Site 3, Splice Region 3, Frame Shift Ins 2, Intron 2, RNA 2, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 82/138 reads (59%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ARID1B | c.3284_3285del p.K1095Rfs*9 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs876657380; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- GJA1 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1554200992, CM030456; ClinVar: pathogenic; called by muse, mutect2, varscan2
- N4BP2L2 | c.2738dup p.N913Kfs*2 (on ENST00000674422; = p.N484Kfs*2 on NM_033111.4) | Frame Shift Ins (INS) | VAF 44/156 reads (28%) | catalogued as rs1158061584; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 75/206 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SOX9 | c.499_501del p.K167del | In Frame Del (DEL) | VAF 50/74 reads (68%) | hotspot (GDC flag); called by pindel, varscan2
- ACAT2 | c.796_798del p.K266del | In Frame Del (DEL) | VAF 28/73 reads (38%) | catalogued as rs1341931392; called by pindel, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 22/41 reads (54%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM18 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.79); PolyPhen benign (0.048); catalogued as rs764655233, COSV99696195; called by muse, mutect2, varscan2
- AQP3 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs760141667, COSV53049138; called by muse, mutect2, varscan2
- ATP1A2 | c.1811G>A p.R604Q | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as rs747238010, CM105888, COSV63404825; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMPR2 | c.325C>T p.Q109* | Nonsense Mutation (SNP) | VAF 47/116 reads (41%) | catalogued as COSV101001732; called by muse, mutect2, varscan2
- C3 | c.1963G>A p.A655T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs1220580146, COSV55573887; called by muse, mutect2, varscan2
- CASP8AP2 | c.4639C>T p.R1547C | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1436988633, COSV99387628; called by muse, mutect2, varscan2
- CCDC58 | c.112G>A p.V38I | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT tolerated (0.7); PolyPhen benign (0.104); catalogued as COSV99360597; called by muse, varscan2
- CDH10 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1431341320, COSV52573483; called by muse, mutect2, varscan2
- CDH24 | c.1978G>A p.V660M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.106); catalogued as rs1242765544, COSV99944076; called by muse, mutect2, varscan2
- CEP120 | c.2724C>T p.N908= | Splice Region (SNP) | VAF 84/240 reads (35%) | catalogued as COSV100071525; called by muse, mutect2, varscan2
- CEP350 | c.1846_1848del p.K616del | In Frame Del (DEL) | VAF 38/134 reads (28%) | catalogued as rs1363903162; called by pindel, varscan2
- CNP | c.547_549del p.K183del | In Frame Del (DEL) | VAF 15/22 reads (68%) | catalogued as rs782706213; called by mutect2, pindel, varscan2
- COG4 | c.1919_1920+1del p.X640_splice | Splice Site (DEL) | VAF 22/56 reads (39%) | catalogued as rs1253001054; called by pindel, varscan2
- CPLANE1 | c.7791A>G p.I2597M | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as rs1458394098, COSV99951949; called by muse, mutect2, varscan2
- CYP1A1 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.19); PolyPhen benign (0.055); catalogued as rs201651069, COSV65698292; called by muse, mutect2, varscan2
- DAGLB | c.985C>A p.H329N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as COSV99766223; called by muse, mutect2, varscan2
- DDX58 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV101153348, COSV65884552; called by muse, mutect2, varscan2
- DEPDC1B | c.1297C>A p.R433S | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV54011057, COSV99409939; called by muse, mutect2, varscan2
- DHX58 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs782666732, COSV99288588; called by muse, mutect2, varscan2
- ECE2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as rs745882263, COSV100668904; called by muse, mutect2, varscan2
- EEF1AKNMT | c.85T>G p.F29V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100676068; called by muse, mutect2, varscan2
- F9 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs766259893, COSV99496956; called by muse, mutect2, varscan2
- FAM118A | c.742_745del p.L248Tfs*16 | Frame Shift Del (DEL) | VAF 32/116 reads (28%) | catalogued as rs767178000; called by pindel, varscan2
- FANCC | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs778951584, COSV100002114, COSV56668025; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAT2 | c.8182C>T p.R2728W | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs201629483; called by muse, mutect2, varscan2
- FCGBP | c.10589G>A p.R3530Q | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as rs1337104307; called by muse, mutect2, varscan2
- GLUD2 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100047143; called by muse, mutect2, varscan2
- GNB1L | c.832C>T p.R278C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758983343, COSV61550136; called by muse, mutect2, varscan2
- GRIK3 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs754997755, COSV100901471, COSV66135314; called by muse, mutect2, varscan2
- HCFC1 | c.4216G>A p.A1406T | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0); catalogued as rs782385254, COSV60078324; called by muse, mutect2, varscan2
- HDAC1 | c.1433_1435del p.E478del | In Frame Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs768269931; called by pindel, varscan2
- HRH2 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as rs1488808803, COSV51574110; called by muse, mutect2, varscan2
- HRNR | c.892C>T p.R298* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as rs1265802700, COSV100914013; called by muse, mutect2, varscan2
- HS3ST3A1 | c.767C>T p.T256M | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as rs776220482, COSV52374630; called by muse, mutect2, varscan2
- HYDIN | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs868676049, COSV99865696; called by mutect2, varscan2
- IL25 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs375944472; called by muse, mutect2, varscan2
- ITIH6 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 76/199 reads (38%) | catalogued as rs764419274, COSV99514098; called by muse, mutect2, varscan2
- JAKMIP3 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754433822, COSV100058422; called by muse, mutect2, varscan2
- KLB | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT tolerated (0.61); PolyPhen benign (0.102); catalogued as rs201377023, COSV99962530; called by muse, mutect2, varscan2
- LRRC4B | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs891529810, COSV65349862; called by muse, mutect2, varscan2
- LRRC74A | c.1282G>A p.V428M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.241); catalogued as rs202056854, COSV99372789; called by muse, mutect2, varscan2
- MAS1L | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); catalogued as COSV101009730; called by muse, mutect2
- MBTPS1 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.635); catalogued as COSV100597865; called by muse, mutect2, varscan2
- MCHR1 | c.955C>T p.R319W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as rs549253450, COSV50763425; called by muse, mutect2, varscan2
- MDGA1 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs371220274; called by muse, mutect2, varscan2
- MGAT5B | c.1754C>T p.A585V (on ENST00000569840 / NM_001199172.2; = p.A583V on NM_144677.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs199872537, COSV56934974; called by muse, mutect2, varscan2
- MNDA | c.1001A>G p.K334R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV63739844, COSV63741720; called by muse, mutect2, varscan2
- MSLN | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.894); catalogued as rs759331194, COSV53499513; called by muse, mutect2, varscan2
- MXRA5 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 79/211 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs753016834, COSV99479644; called by muse, mutect2, varscan2
- NEB | c.15908A>T p.E5303V | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV51464167; called by muse, mutect2, varscan2
- NLRP1 | c.1142C>A p.A381D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV52565931; called by muse, mutect2, varscan2
- NSD1 | c.6304_6306del p.K2102del | In Frame Del (DEL) | VAF 25/55 reads (45%) | catalogued as rs1386090177; called by pindel, varscan2
- NUDT16L1 | c.601_603del p.K201del | In Frame Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs1283990748; called by pindel, varscan2
- NUP62 | c.845_850del p.T282_S283del | In Frame Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs1038713350; called by pindel, varscan2
- OR14K1 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV51721306, COSV99315338; called by muse, mutect2, varscan2
- OR3A1 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.317); catalogued as rs748830456, COSV60162725; called by muse, mutect2, varscan2
- P2RX7 | c.380C>T p.T127M | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as rs200025457, COSV55858004; called by muse, mutect2, varscan2
- PACS2 | c.290_292del p.S97del | In Frame Del (DEL) | VAF 16/40 reads (40%) | catalogued as rs782429503; called by mutect2, pindel, varscan2
- PIKFYVE | c.2471C>T p.T824I | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100011550; called by muse, mutect2, varscan2
- PLD1 | c.2932G>C p.V978L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as COSV100644098; called by muse, mutect2, varscan2
- POP1 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 14/35 reads (40%) | catalogued as rs374710242; called by muse, mutect2, varscan2
- PPL | c.2311_2313del p.K771del | In Frame Del (DEL) | VAF 27/84 reads (32%) | catalogued as rs772519097; called by mutect2, pindel, varscan2
- PPP1R10 | c.474_476del p.K159del | In Frame Del (DEL) | VAF 66/187 reads (35%) | catalogued as rs776375912; called by pindel, varscan2
- PPP6R2 | c.2873_2875del p.E958del (on ENST00000216061 / NM_001365836.1; = p.E924del on NM_014678.5 and 4 other RefSeq transcripts) | In Frame Del (DEL) | VAF 17/49 reads (35%) | catalogued as rs1373711027; called by mutect2, pindel, varscan2
- PRAME | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV101287279; called by muse, mutect2
- PRRC2A | c.1178C>A p.A393E | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100784641; called by muse, mutect2, varscan2
- QRFPR | c.1123_1124del p.K375Vfs*18 | Frame Shift Del (DEL) | VAF 62/186 reads (33%) | catalogued as rs780743673; called by mutect2, pindel, varscan2
- RASGRF1 | c.947C>T p.T316M | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751054636, COSV101369774; called by muse, mutect2, varscan2
- RGS9BP | c.89C>T p.S30L | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.182); catalogued as rs959893417, COSV100043214; called by muse, mutect2, varscan2
- RIOK3 | c.179+1G>A p.X60_splice | Splice Site (SNP) | VAF 16/38 reads (42%) | catalogued as rs373422920; called by muse, mutect2, varscan2
- RMDN1 | c.885_887del p.E295del | In Frame Del (DEL) | VAF 48/167 reads (29%) | catalogued as rs1239318639; called by pindel, varscan2
- RTEL1 | c.2351_2353del p.F784del | In Frame Del (DEL) | VAF 10/24 reads (42%) | catalogued as rs771771098; called by pindel, varscan2
- RYR1 | c.10496G>A p.R3499Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs138324438, COSV100617173; called by muse, mutect2, varscan2
- RYR3 | c.4466G>A p.R1489Q | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370542262; called by muse, mutect2, varscan2
- SALL2 | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764828751, COSV100444630; called by muse, mutect2, varscan2
- SCN1A | c.5657G>A p.R1886Q (on ENST00000303395 / NM_001202435.3; = p.R1875Q on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as rs1559100385, CD031887, CM134117, COSV57665487; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC15A2 | c.1005G>T p.G335= | Splice Region (SNP) | VAF 44/101 reads (44%) | catalogued as rs777104856, COSV55199473, COSV99815908; called by muse, mutect2, varscan2
- SLC9A5 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.44); PolyPhen benign (0.011); catalogued as COSV100237655; called by muse, mutect2, varscan2
- SPART | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs900702066, COSV62083633; called by muse, varscan2
- SPATA17 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs769224894, COSV65123595; called by muse, mutect2, varscan2
- SPATA4 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 60/194 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142260014; called by muse, mutect2, varscan2
- SPTBN1 | c.3938G>A p.W1313* | Nonsense Mutation (SNP) | VAF 24/79 reads (30%) | catalogued as COSV61694832; called by muse, mutect2, varscan2
- SREBF1 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs568851975, COSV55420412; called by muse, mutect2, varscan2
- TEFM | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV58979793; called by muse, mutect2, varscan2
- TENM1 | c.5482C>T p.R1828* | Nonsense Mutation (SNP) | VAF 40/90 reads (44%) | catalogued as rs756982022, COSV100950014; called by muse, mutect2, varscan2
- THOC5 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs1268231076, COSV100803662; called by muse, mutect2, varscan2
- TMEM74 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV52462767, COSV99865982; called by muse, mutect2, varscan2
- TRPM6 | c.2810C>T p.A937V | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.179); catalogued as rs558534348, COSV100666535; called by muse, mutect2, varscan2
- TUBA3E | c.6C>T p.R2= | Splice Region (SNP) | VAF 48/134 reads (36%) | catalogued as rs369827309; called by muse, mutect2, varscan2
- U2SURP | c.31_33del p.K11del | In Frame Del (DEL) | VAF 37/128 reads (29%) | catalogued as rs1462023572; called by mutect2, pindel, varscan2
- UBE4B | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs548707778, COSV53538719; called by muse, mutect2, varscan2
- UBR1 | c.1217A>T p.D406V | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99317973; called by muse, mutect2, varscan2
- VPS13C | c.8791C>T p.P2931S (on ENST00000644861 / NM_020821.3; = p.P2888S on NM_017684.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV99830500; called by muse, varscan2
- WDPCP | c.2230G>A p.G744S | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99707170; called by muse, mutect2, varscan2
- ZFHX4 | c.9781C>A p.Q3261K | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99268515; called by muse, mutect2, varscan2
- ZFP30 | c.1540C>T p.R514* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as rs146564645; called by muse, mutect2, varscan2
- ZMYND11 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.145); catalogued as COSV100556971; called by muse, mutect2, varscan2
- ZNF41 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 66/149 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100492364; called by muse, mutect2, varscan2
- ZNF418 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs773985943, COSV68675684; called by muse, mutect2, varscan2
- ZNF574 | c.2041C>T p.R681* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99726596; called by muse, mutect2, varscan2
- AMER1 | c.1670_1671del p.E557Gfs*22 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by pindel, varscan2
- ANK3 | c.5264_5265del p.V1755Gfs*6 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by pindel, varscan2
- ARAP2 | c.4063_4065del p.E1355del | In Frame Del (DEL) | VAF 68/199 reads (34%) | called by pindel, varscan2
- ARFGEF1 | c.2663_2664del p.K888Rfs*10 | Frame Shift Del (DEL) | VAF 80/256 reads (31%) | called by mutect2, pindel, varscan2
- ARID1A | c.4217_4221del p.P1406Rfs*37 | Frame Shift Del (DEL) | VAF 24/63 reads (38%) | called by mutect2, pindel
- BCLAF3 | c.1722del p.H575Tfs*2 | Frame Shift Del (DEL) | VAF 62/176 reads (35%) | called by mutect2, pindel, varscan2
- C12orf66 | c.355del p.E119Kfs*21 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- CCDC178 | c.463_464del p.K155Vfs*20 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by mutect2, pindel, varscan2
- CDH1 | c.1091_1092del p.T364Sfs*3 | Frame Shift Del (DEL) | VAF 24/89 reads (27%) | called by pindel, varscan2
- CYB561A3 | c.99_101del p.G34del | In Frame Del (DEL) | VAF 8/34 reads (24%) | called by pindel, varscan2
- FBXO34 | c.1507_1509del p.K503del | In Frame Del (DEL) | VAF 31/84 reads (37%) | called by mutect2, pindel, varscan2
- GATA6 | c.1454_1455del p.K485Rfs*11 | Frame Shift Del (DEL) | VAF 43/128 reads (34%) | called by mutect2, pindel, varscan2
- GPR52 | c.994_997del p.S332Rfs*10 | Frame Shift Del (DEL) | VAF 25/75 reads (33%) | called by mutect2, pindel, varscan2
- MAMDC2 | c.124_125del p.L42Afs*6 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by pindel, varscan2
- MARCHF5 | c.70_72del p.D24del | In Frame Del (DEL) | VAF 22/65 reads (34%) | called by pindel, varscan2
- MARK3 | c.90_91del p.R31Yfs*9 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | called by pindel, varscan2
- NUP205 | c.1969_1971del p.P657del | In Frame Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- OR14K1 | c.81del p.L27Ffs*5 | Frame Shift Del (DEL) | VAF 56/174 reads (32%) | called by pindel, varscan2
- PTK2 | c.2735del p.P912Lfs*17 | Frame Shift Del (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel, varscan2
- PTPN23 | c.1826_1827del p.Y609* | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- RBM5 | c.728_729del p.V243Gfs*18 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by pindel, varscan2
- RGMB | c.577_579del p.N193del (on ENST00000513185 / NM_001366508.1; = p.N234del on NM_001012761.3 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 10/24 reads (42%) | called by pindel, varscan2
- RNF43 | c.896_897del p.V299Gfs*143 | Frame Shift Del (DEL) | VAF 11/26 reads (42%) | called by pindel, varscan2
- SERBP1 | c.606-2_607del p.X202_splice | Splice Site (DEL) | VAF 48/139 reads (35%) | called by mutect2, pindel, varscan2
- SLC4A7 | c.934_936del p.S313del | In Frame Del (DEL) | VAF 62/177 reads (35%) | called by mutect2, pindel, varscan2
- SP3 | c.693_697del p.G232Sfs*22 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.546_548del p.W182del | In Frame Del (DEL) | VAF 58/187 reads (31%) | called by pindel, varscan2
- SPTLC1 | c.653_654del p.E218Afs*44 | Frame Shift Del (DEL) | VAF 26/94 reads (28%) | called by mutect2, pindel
- THG1L | c.20_24del p.V7Gfs*36 | Frame Shift Del (DEL) | VAF 15/49 reads (31%) | called by mutect2, pindel, varscan2
- TPTE2 | c.1324_1327del p.D442Kfs*3 (on ENST00000400230 / NM_199254.2; = p.D365Kfs*3 on NM_130785.3) | Frame Shift Del (DEL) | VAF 10/52 reads (19%) | called by mutect2, pindel, varscan2
- TRIM26 | c.1337_1338del p.V446Efs*33 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by pindel, varscan2
- VDAC2 | c.343_344del p.S115Tfs*9 | Frame Shift Del (DEL) | VAF 109/363 reads (30%) | called by pindel, varscan2
- VPS13C | c.8754_8755del p.V2920Efs*6 (on ENST00000644861 / NM_020821.3; = p.V2877Efs*6 on NM_017684.5) | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | called by pindel, varscan2
- WNK4 | c.1908_1909del p.S637Pfs*14 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- CC2D1B | c.1902C>T p.C634= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as rs751157387, COSV99430366; called by muse, mutect2, varscan2
- CCNA1 | c.507C>T p.L169= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV99714995; called by muse, mutect2, varscan2
- CGB1 | c.66G>A p.P22= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs200371312, COSV100031440; called by muse, mutect2, varscan2
- CORO1A | c.162C>T p.S54= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as rs536390638, COSV54631117; called by muse, mutect2, varscan2
- CSF2RB | c.585C>A p.A195= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV99454140, COSV99454558; called by muse, mutect2, varscan2
- DZIP1L | c.1764C>T p.S588= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs141369259; called by muse, mutect2, varscan2
- FBN3 | c.2511C>A p.T837= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99561982; called by muse, mutect2, varscan2
- FH | c.1305G>T p.V435= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs772415507, COSV100845099; called by muse, mutect2, varscan2
- GAS7 | c.894C>T p.S298= (on ENST00000432992 / NM_201433.2; = p.S158= on NM_003644.3) | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs756352154, COSV100094796; called by muse, mutect2, varscan2
- GRM1 | c.2361C>T p.I787= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs762664865, COSV99269441; called by muse, mutect2, varscan2
- HOXD3 | c.1176C>T p.A392= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as rs760834566, COSV50882979; called by muse, mutect2, varscan2
- IQGAP2 | c.726G>A p.A242= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs774632080, COSV99166621, COSV99167389; called by muse, mutect2, varscan2
- ITGB5 | c.1386G>A p.T462= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs775683311, COSV56149521; called by muse, mutect2, varscan2
- KCNK4 | c.162C>T p.S54= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as COSV100487455; called by muse, mutect2, varscan2
- LAMA4 | c.2544G>A p.S848= (on ENST00000230538 / NM_001105206.3; = p.S841= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs111587919, COSV100039631; called by muse, mutect2, varscan2
- LRRK2 | c.6522C>T p.T2174= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as rs149013010; called by muse, mutect2, varscan2
- MAML3 | c.1497G>A p.Q499= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs574825040, COSV59075209; called by muse, varscan2
- MEPE | c.429C>T p.G143= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as rs145299039, COSV100734956; called by muse, mutect2, varscan2
- MYH13 | c.525C>T p.I175= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV52844433; called by muse, mutect2
- NEK1 | c.3537C>T p.C1179= | Silent (SNP) | VAF 38/90 reads (42%) | catalogued as rs772515579, COSV71457710; called by muse, mutect2, varscan2
- NUDT2 | c.321C>T p.L107= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as rs748007466, COSV100663591; called by muse, mutect2, varscan2
- ORAI2 | c.147G>A p.S49= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs374851154; called by muse, mutect2, varscan2
- PCDHB3 | c.1329C>T p.D443= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as COSV50574236, COSV99166875; called by muse, mutect2, varscan2
- PIK3C2A | c.237T>C p.P79= | Silent (SNP) | VAF 69/214 reads (32%) | catalogued as COSV99791337; called by muse, mutect2, varscan2
- PIR | c.615C>T p.P205= | Silent (SNP) | VAF 71/160 reads (44%) | catalogued as rs554199837, COSV100990711; called by muse, mutect2, varscan2
- PRF1 | c.363G>A p.A121= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs146358730; called by muse, mutect2, varscan2
- SHROOM4 | c.408C>T p.D136= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs1299682253, COSV56785578; called by muse, mutect2, varscan2
- SLC25A5 | c.636C>A p.I212= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV100510502, COSV58629753; called by muse, mutect2, varscan2
- SPACA1 | c.243C>T p.F81= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs769128092, COSV52761633; called by muse, mutect2, varscan2
- SRL | c.303G>A p.P101= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as rs368659942; called by muse, mutect2, varscan2
- USP54 | c.4083C>T p.H1361= | Silent (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- WWC3 | c.2046A>C p.T682= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as COSV101081911; called by muse, mutect2, varscan2
- ZDHHC3 | c.516C>T p.F172= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV56101060; called by muse, mutect2, varscan2
- AL133467.5 | chr14:95663591 del AG | 3'Flank (DEL) | VAF 8/26 reads (31%) | catalogued as rs762437415; called by mutect2, pindel, varscan2
- DIP2C | c.157+1644C>T | Intron (SNP) | VAF 7/15 reads (47%) | catalogued as rs766358951; called by muse, mutect2, varscan2
- DST | c.4297-2061C>T | Intron (SNP) | VAF 50/165 reads (30%) | catalogued as rs770480438, COSV99760547; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MIR379 | n.28G>A | RNA (SNP) | VAF 16/54 reads (30%) | catalogued as rs115827677; called by muse, mutect2, varscan2
- MUC2 | chr11:1099590 A>G | 5'Flank (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2
- PLEKHA8P1 | n.991G>A | RNA (SNP) | VAF 78/218 reads (36%) | called by muse, mutect2, varscan2
- TENM1 | c.-2A>G | 5'UTR (SNP) | VAF 42/125 reads (34%) | catalogued as COSV100951171; called by muse, mutect2, varscan2
